Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A24Z, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A24Z-01A (Primary Tumor).

HI/AA Discrepancy		✓

Final Diagnosis

Breast, left, total mastectomy: Infiltrating ductal carcinoma, Nottingham grade II (of III), [tubules 2/3, nuclei 2/3, mitoses 3/3; Nottingham score 7/9], forming a 4.2 x 4.0 x 3.0 cm mass located in the upper outer quadrant of the breast [AJCC pT2]. Focal ductal carcinoma in situ, intermediate nuclear grade, comprising approximately 5% of tumor volume. The non-neoplastic breast parenchyma shows nonproliferative fibrocystic changes. Biopsy site changes present. The tumor does not involve the nipple, overlying skin, or underlying chest wall. All surgical resection margins, including deep margin, are negative for tumor (minimum tumor free margin, 1.5 cm, anterior margin).

Lymph nodes, left axillary sentinel, excision: Multiple (8) left axillary sentinel lymph nodes are negative for tumor (AJCCpN0(i-)(sn)). Blue dye was identified in lymph node Nos. 2A, 2B, and 2C. No blue dye was identified in lymph node Nos. 1, 3, 4, 5, and 6. Immunohistochemical cytokeratin stain was performed on the paraffin embedded sentinel lymph node tissue and confirms the H&E impression.

Estrogen and progesterone receptor analysis and HER2/neu have been ordered on paraffin embedded tissues.

ICD-0-3

carcinoma, infiltrating duct, nos 8500/3

Site: breast, nos C50.9

hw
4/25/11

Source: NCI Genomic Data Commons file 22489f23-84c2-4f40-9562-7678b66d09aa (TCGA-AR-A24Z.AD07F611-0EEA-4890-A02C-6DA3F5F57C45.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).